Somatic mutation profile of tumor specimen TCGA-TQ-A7RR-01A (aliquot TCGA-TQ-A7RR-01A-21D-A34A-08) from TCGA case TCGA-TQ-A7RR, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 38.4 years (14,022 days).
Specimen TCGA-TQ-A7RR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01cc419d-cd7a-4cfc-b024-b473fb6b5f85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TQ-A7RR-10A (Blood Derived Normal), aliquot TCGA-TQ-A7RR-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11d7f90f-3117-430b-b0b5-ffea26421fb7

The open-access MAF lists 29 somatic variants for this specimen: 20 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 7, Frame Shift Del 3, 3'UTR 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 45/123 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 4/13 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.709A>G p.M237V | Missense Mutation (SNP) | VAF 25/78 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs730882004, COSV52701833, COSV52875518, COSV53198341; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CES3 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.219); catalogued as COSV100309869; called by muse, mutect2, varscan2
- CTR9 | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs966128559, COSV63727761; called by muse, mutect2, varscan2
- FSTL5 | c.679T>C p.F227L | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100053965; called by muse, mutect2, varscan2
- ICOS | c.463A>G p.I155V | Missense Mutation (SNP) | VAF 15/250 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV100320303; called by muse, mutect2
- MYO1B | c.556A>C p.S186R | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV100268876; called by muse, mutect2, varscan2
- OR2M3 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 93/282 reads (33%) | SIFT tolerated (0.95); PolyPhen benign (0.012); catalogued as rs547891650, COSV71759184, COSV71759200; called by muse, mutect2, varscan2
- OTOP3 | c.1525C>A p.L509I | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV100172736; called by muse, mutect2, varscan2
- RRP12 | c.55A>G p.K19E | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as COSV100213069; called by muse, mutect2, varscan2
- SPDYC | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.468); catalogued as rs370497227, COSV65865338; called by muse, mutect2
- SSTR4 | c.1040A>G p.Y347C | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs778922196, COSV99658498; called by muse, mutect2, varscan2
- SYNRG | c.3655G>A p.A1219T | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.089); catalogued as rs1231711925; called by muse, mutect2, varscan2
- TMPRSS11E | c.293A>G p.E98G | Missense Mutation (SNP) | VAF 74/226 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1379000493, COSV100542296; called by muse, varscan2
- TTN | c.27290C>T p.A9097V (on ENST00000591111; = p.A8170V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/118 reads (17%) | PolyPhen benign (0.041); catalogued as COSV100603264; called by muse, mutect2, varscan2
- ATRX | c.2264del p.N755Mfs*13 | Frame Shift Del (DEL) | VAF 169/294 reads (57%) | called by mutect2, pindel, varscan2
- EEFSEC | c.981del p.L329Cfs*20 | Frame Shift Del (DEL) | VAF 23/76 reads (30%) | called by mutect2, varscan2
- FIBCD1 | c.1368_1380del p.V457Afs*79 | Frame Shift Del (DEL) | VAF 11/36 reads (31%) | called by mutect2, pindel, varscan2
- NREP | c.-14_3+1del | Splice Site (DEL) | VAF 46/191 reads (24%) | called by mutect2, pindel, varscan2
- APOB | c.9912G>A p.L3304= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as COSV99264756; called by muse, mutect2, varscan2
- B3GALT5 | c.789G>A p.Q263= | Silent (SNP) | VAF 8/149 reads (5%) | catalogued as COSV100563339; called by muse, mutect2
- CFAP44 | c.2850G>A p.E950= | Silent (SNP) | VAF 29/193 reads (15%) | catalogued as COSV99869262; called by muse, mutect2, varscan2
- ELMO2 | c.1305C>T p.H435= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs1334541025, COSV99281553; called by muse, mutect2, varscan2
- GMPR2 | c.843C>T p.G281= (on ENST00000355299 / NM_001351022.2; = p.G299= on NM_016576.5) | Silent (SNP) | VAF 12/110 reads (11%) | catalogued as rs929281874, COSV99945399; called by muse, mutect2, varscan2
- LVRN | c.1209A>G p.T403= | Silent (SNP) | VAF 9/238 reads (4%) | catalogued as COSV100773388; called by muse, mutect2
- ZNF454 | c.39G>A p.S13= | Silent (SNP) | VAF 31/110 reads (28%) | catalogued as rs770644793, COSV100194756; called by muse, mutect2, varscan2
- COL4A4 | c.*2G>T | 3'UTR (SNP) | VAF 112/792 reads (14%) | catalogued as COSV100306524; called by muse, mutect2, varscan2
- MIR1251 | n.28T>C | RNA (SNP) | VAF 34/55 reads (62%) | called by muse, mutect2, varscan2
